Somatic mutation profile of tumor specimen TARGET-30-PAUKRF-01A (aliquot TARGET-30-PAUKRF-01A-01D) from TARGET case TARGET-30-PAUKRF, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Overlapping lesion of retroperitoneum and peritoneum; Age at diagnosis: 2.1 years (759 days).
Specimen TARGET-30-PAUKRF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d5b81fc5-65ac-47a3-a0b1-fcea793bb024.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAUKRF-10A (Blood Derived Normal), aliquot TARGET-30-PAUKRF-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0acd6952-9859-4fee-b125-95b9bb85ac0c

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.1657G>T p.E553* | Nonsense Mutation (SNP) | VAF 15/161 reads (9%) | catalogued as rs1569326367; ClinVar: uncertain significance; called by muse, mutect2
- ASXL2 | c.2549C>A p.A850E | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.081); catalogued as COSV55455038; called by muse, mutect2, varscan2
- RUNDC1 | c.1460C>A p.A487D | Missense Mutation (SNP) | VAF 16/279 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); called by muse, mutect2
- TPTE | c.-122T>C | 5'UTR (SNP) | VAF 21/153 reads (14%) | called by muse, mutect2, varscan2
